Somatic mutation profile of tumor specimen TCGA-EJ-7789-01A (aliquot TCGA-EJ-7789-01A-11D-2114-08) from TCGA case TCGA-EJ-7789, project TCGA-PRAD (Prostate Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Acinar cell carcinoma; Tissue or organ of origin: Prostate gland; Age at diagnosis: 66.0 years (24,107 days).
Specimen TCGA-EJ-7789-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 3690f3df-04d1-4965-83b5-5cb2b3045f54.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-EJ-7789-10A (Blood Derived Normal), aliquot TCGA-EJ-7789-10A-01D-2114-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/0a4f79ba-a9a9-4f60-b335-d16e26a0561a

The open-access MAF lists 30 somatic variants for this specimen: 22 protein-altering or splice-affecting, 7 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 18, Silent 7, Frame Shift Del 2, Nonstop Mutation 1, RNA 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ACTR5 | c.1747G>A p.A583T | Missense Mutation (SNP) | VAF 23/37 reads (62%) | SIFT tolerated (0.38); PolyPhen benign (0.007); catalogued as COSV54760449; called by muse, mutect2, varscan2
- APOB | c.8429C>A p.A2810E | Missense Mutation (SNP) | VAF 46/172 reads (27%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.907); catalogued as COSV51931643; called by muse, mutect2, varscan2
- CNTN3 | c.371T>A p.F124Y | Missense Mutation (SNP) | VAF 9/20 reads (45%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.75); catalogued as COSV55168112; called by muse, mutect2, varscan2
- DNAH5 | c.13531A>G p.M4511V | Missense Mutation (SNP) | VAF 168/254 reads (66%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV54217932; called by muse, mutect2, varscan2
- DOCK7 | c.5961G>C p.E1987D (on ENST00000635253 / NM_001367561.1; = p.E1956D on NM_033407.3) | Missense Mutation (SNP) | VAF 58/141 reads (41%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.981); catalogued as COSV52002218; called by muse, mutect2, varscan2
- FOXA1 | c.760T>G p.F254V | Missense Mutation (SNP) | VAF 14/32 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51643454; called by muse, mutect2, varscan2
- HLA-DRA | c.728G>A p.R243H | Missense Mutation (SNP) | VAF 46/98 reads (47%) | SIFT tolerated (0.19); PolyPhen benign (0.021); catalogued as rs764172368, COSV66622675; called by muse, mutect2, varscan2
- INO80 | c.4573C>A p.P1525T | Missense Mutation (SNP) | VAF 29/78 reads (37%) | SIFT tolerated, low confidence (0.29); PolyPhen benign (0.015); catalogued as COSV62737389; called by muse, mutect2, varscan2
- KRIT1 | c.262+1G>A p.X88_splice | Splice Site (SNP) | VAF 33/110 reads (30%) | catalogued as COSV60667542; called by muse, mutect2, varscan2
- NAV2 | c.86C>A p.P29Q | Missense Mutation (SNP) | VAF 10/28 reads (36%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.052); catalogued as COSV62320236; called by muse, mutect2, varscan2
- NOTCH3 | c.5500C>T p.R1834W | Missense Mutation (SNP) | VAF 18/39 reads (46%) | SIFT deleterious (0); PolyPhen possibly damaging (0.846); catalogued as rs550464740, COSV54632092; called by muse, mutect2, varscan2
- POM121L12 | c.787G>A p.A263T | Missense Mutation (SNP) | VAF 64/106 reads (60%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.045); catalogued as rs749141757, COSV68692580, COSV68693810; called by muse, mutect2, varscan2
- POMC | c.542C>T p.T181I | Missense Mutation (SNP) | VAF 4/16 reads (25%) | SIFT deleterious (0.02); PolyPhen benign (0.015); catalogued as COSV53034653; called by muse, mutect2
- SDK1 | c.886G>T p.V296L | Missense Mutation (SNP) | VAF 34/94 reads (36%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as COSV67364268; called by muse, mutect2, varscan2
- SRPX | c.965T>A p.V322D | Missense Mutation (SNP) | VAF 9/46 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.642); catalogued as COSV59438038; called by muse, mutect2, varscan2
- SSH3 | c.1951C>T p.H651Y | Missense Mutation (SNP) | VAF 42/98 reads (43%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.012); catalogued as COSV57384298; called by muse, mutect2, varscan2
- TGFB1 | c.295C>A p.P99T | Missense Mutation (SNP) | VAF 16/46 reads (35%) | SIFT tolerated (0.94); PolyPhen possibly damaging (0.501); catalogued as rs753186435, COSV54683912; called by muse, mutect2, varscan2
- ZNF439 | c.700del p.R234Efs*112 | Frame Shift Del (DEL) | VAF 39/98 reads (40%) | catalogued as COSV58310221; called by mutect2, pindel, varscan2
- LAMTOR5 | c.275_*14del | Nonstop Mutation (DEL) | VAF 32/94 reads (34%) | called by mutect2, pindel, varscan2
- TAS2R38 | c.953G>C p.S318T | Missense Mutation (SNP) | VAF 10/114 reads (9%) | SIFT tolerated (0.59); PolyPhen benign (0.025); called by muse, mutect2
- TRBV2 | c.13C>A p.L5I | Missense Mutation (SNP) | VAF 41/142 reads (29%) | SIFT deleterious (0.03); PolyPhen benign (0.376); called by muse, mutect2, varscan2
- ZNF226 | c.2201_2202del p.K734Sfs*22 | Frame Shift Del (DEL) | VAF 33/131 reads (25%) | called by mutect2, pindel, varscan2
- CMTR1 | c.784C>T p.L262= | Silent (SNP) | VAF 15/39 reads (38%) | catalogued as COSV65090087; called by muse, mutect2, varscan2
- GTF2B | c.834T>A p.A278= | Silent (SNP) | VAF 57/123 reads (46%) | catalogued as COSV65136848; called by muse, mutect2, varscan2
- LCMT2 | c.1867T>C p.L623= | Silent (SNP) | VAF 45/83 reads (54%) | catalogued as rs538083093, COSV59790105; called by muse, mutect2, varscan2
- MUC16 | c.30366C>A p.I10122= | Silent (SNP) | VAF 16/50 reads (32%) | catalogued as rs377149070; called by muse, mutect2, varscan2
- OR2L2 | c.369G>T p.V123= | Silent (SNP) | VAF 63/134 reads (47%) | catalogued as COSV63551664; called by muse, mutect2, varscan2
- PPP1R42 | c.549G>C p.V183= | Silent (SNP) | VAF 12/95 reads (13%) | catalogued as COSV61207390; called by muse, mutect2, varscan2
- SYCP2L | c.1476C>T p.F492= | Silent (SNP) | VAF 29/59 reads (49%) | catalogued as rs377724008; called by muse, mutect2, varscan2
- LINC02877 | n.294A>C | RNA (SNP) | VAF 147/331 reads (44%) | called by muse, mutect2, varscan2
